Somatic mutation profile of tumor specimen MP2PRT-PAVSXY-TMP1-A (aliquot MP2PRT-PAVSXY-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVSXY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (867 days).
Specimen MP2PRT-PAVSXY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dd7c550-de49-468e-962d-a7ab07c485fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSXY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSXY-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/476eb7aa-885a-4c01-96cc-e56d6a51b38a

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.20522C>T p.S6841F | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs753979916; called by muse, mutect2, varscan2
- CFAP54 | c.5294C>G p.S1765C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV61571702; called by muse, mutect2, varscan2
- CRP | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV99660752; called by muse, mutect2, varscan2
- FOXI1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 57/673 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60388173; called by muse, mutect2
- HAUS3 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 19/390 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1479801870; called by muse, mutect2
- ITGB8 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56006174; called by muse, mutect2, varscan2
- NDST3 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99630002; called by muse, mutect2, varscan2
- NUP107 | c.1361G>C p.R454P | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57494068; called by muse, mutect2, varscan2
- POLR2B | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs769733869; called by muse, mutect2
- TPBG | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63882669; called by muse, varscan2
- TTN | c.91081G>C p.E30361Q (on ENST00000591111; = p.E22937Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/346 reads (5%) | PolyPhen benign (0.155); catalogued as COSV60177770; called by muse, mutect2
- APOE | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 66/714 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- ARMC4 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ATXN1 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMTA1 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); called by muse, mutect2
- GLP2R | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 28/712 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); called by muse, mutect2
- MTHFD1L | c.752A>C p.Q251P | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGM5 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN9A | c.3878G>A p.R1293K (on ENST00000303354; = p.R1282K on NM_002977.3) | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A2 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STMND1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 36/678 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2
- TAF1 | c.1700A>G p.N567S (on ENST00000373790 / NM_138923.4; = p.N588S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/147 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ZNF875 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.441); called by muse, mutect2
- CNP | c.162C>T p.I54= | Silent (SNP) | VAF 141/649 reads (22%) | called by muse, mutect2, varscan2
- DIS3 | c.837A>G p.G279= | Silent (SNP) | VAF 21/276 reads (8%) | called by muse, mutect2
- MARCKS | c.240G>A p.A80= | Silent (SNP) | VAF 18/520 reads (3%) | called by muse, mutect2
- SLCO1A2 | c.828G>A p.E276= | Silent (SNP) | VAF 46/169 reads (27%) | called by muse, mutect2, varscan2
- TBCEL | c.615C>T p.L205= | Silent (SNP) | VAF 57/337 reads (17%) | catalogued as rs1416261113; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+4338G>A | Intron (SNP) | VAF 34/306 reads (11%) | catalogued as rs1039416543; called by muse, varscan2
